Gene-level copy-number profile of tumor specimen ALCH-B2T8-TTP1-A from ALCHEMIST case ALCH-B2T8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.5 years (19,524 days).
Specimen ALCH-B2T8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0dcb70c2-e5fb-48d6-a1da-2ea37c9a424d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2T8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/fa64e771-5b11-4aec-9a93-09d8970cc463

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 5,661; copy number 2: 47,629; copy number 3: 4,735; copy number 4: 57; copy number 5: 56; copy number 6: 74; copy number 7: 29; copy number 8: 104; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,424,776–6,520,074, 5 genes (within-gene range 0–1): ESPN, MIR4252, AL031848.1, TNFRSF25, PLEKHG5.
- chr7:56,805,336–56,808,148, 1 gene: CICP28.
- chr14:105,621,116–105,621,180, 1 gene: MIR8071-1.
- chr15:25,170,723–25,250,940, 44 genes (within-gene range 0–1): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:70,661,204–70,686,053, 2 genes: MTSS2, AC020763.4.
- chr17:64,778,842–64,778,937, 1 gene (within-gene range 0–3): AC103810.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 264 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–438,291, 15 genes, copy number 5–8 (within-gene range 4–8): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1.
- chr5:535,840–1,295,068, 24 genes, copy number 5–12: MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr5:1,544,107–3,536,094, 33 genes, copy number 5–8: AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017.
- chr5:5,046,796–7,391,907, 41 genes, copy number 5–7: AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1, AC010266.2, AC010266.1, AC026797.1, HMGB3P3, LINC02145, MED10, UBE2QL1, AC027334.1, LINC01018, NSUN2, SRD5A1, LINC02102, TENT4A, LINC02236, AC122710.2, LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1, Metazoa_SRP, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142.
- chr5:9,035,033–10,440,388, 35 genes, copy number 6 (within-gene range 4–6): SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6.
- chr5:10,504,996–10,777,062, 12 genes, copy number 6: LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1.
- chr5:12,794,100–14,961,393, 25 genes, copy number 5–6 (within-gene range 4–6): AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1.
- chr5:16,067,139–20,575,873, 77 genes, copy number 6–8 (broad region; genes not listed).
- chr14:18,395,626–18,419,273, 2 genes, copy number 5–6: CR383658.2, BNIP3P6.

Autosomal genes at a single copy (total copy number 1): 5,661. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
